Gene-level copy-number profile of tumor specimen TCGA-OR-A5JS-01A from TCGA case TCGA-OR-A5JS, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 65.8 years (24,017 days).
Specimen TCGA-OR-A5JS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.c45a32aa-07e5-43d9-84f0-4e0aac523f92.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5JS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7fc6727a-3d68-46e9-b612-89266d5ae140

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 387; copy number 2: 9,821; copy number 3: 16,436; copy number 4: 32,013; copy number 6: 715; copy number 8: 53; copy number 9: 33; copy number 11: 75; copy number 12: 8; copy number 13: 73; copy number 14: 30; copy number 15: 31; copy number 16: 26; copy number 22: 4; copy number 25: 31; copy number 26: 17; copy number 28: 22; copy number 30: 4; copy number 35: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5JS-01A-11D-A29H-01): tumor purity 0.85, ploidy 3.42, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:92,675,956–92,844,992, 3 genes (within-gene range 0–14): AC026780.2, AC008517.1, LDHBP3.
- chr5:102,371,774–103,253,519, 11 genes (within-gene range 0–6): SLCO6A1, AC094108.1, LINC00492, LINC00491, AC099487.1, AC099487.2, PAM, EIF3KP1, GIN1, PPIP5K2, AC011362.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 366 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:92,889,387–95,961,851, 47 genes, copy number 11–14: CCT7P2, LINC02058, AC012625.1, AC026408.1, POLD2P1, NR2F1-AS1, NR2F1, AC106818.1, FAM172A, MIR2277, AC106818.2, NPM1P27, POU5F2, AC108102.1, AC099501.1, AC114980.1, AC117528.1, KIAA0825, MTND5P12, MTND6P3, MTCYBP35, AC093311.1, AC025766.1, SLF1, MCTP1, AC008534.1, RPL7P18, AC008534.2, MCTP1-AS1, FAM81B, RTRAFP2, TTC37, RNU6-308P, ARSK, GPR150, RFESD, SPATA9, AC008840.1, RHOBTB3, GLRX, HSPD1P11, GGCTP1, AC008592.3, LINC01554, AC008592.4, AC008592.1, ELL2.
- chr5:95,964,999–95,986,311, 2 genes, copy number 11: AC008592.2, FABP5P5.
- chr5:99,489,559–100,733,386, 28 genes, copy number 9–28: AC114324.2, AC114324.1, GUSBP8, LINC02113, AC008837.1, AC008837.2, CRLF3P2, EEF1A1P20, Y_RNA, MTCYBP22, MTND6P22, MTND5P10, MTND4P35, MTND4LP5, MTND3P19, MTCO3P22, MTATP6P2, MTCO2P22, MTCO1P22, GUSBP7, RNU6-1119P, AC113385.3, AC113385.2, AC113385.1, AC021086.1, FAM174A, AC027315.1, RN7SKP62.
- chr5:106,415,576–111,739,726, 55 genes, copy number 9–35 (within-gene range 2–35): AC027313.1, AC114940.1, AC114940.2, LINC01950, PSMC1P5, EFNA5, AC024587.2, AC024587.1, RN7SL782P, RN7SKP122, FBXL17, AC008462.1, AC133134.1, LINC01023, FER, AC034207.1, AC008871.1, Y_RNA, AC109481.1, RNU6-47P, GJA1P1, AC116428.1, AC008467.1, PJA2, AC010625.1, AC091917.3, AC091917.2, AC091917.1, KRT18P42, MAN2A1-DT, MAN2A1, RN7SKP230, AC008417.1, LINC01848, PGAM5P1, TMEM232, MIR548F3, AC008650.1, SLC25A46, AC008782.1, BCLAF1P1, AC010395.1, AC010395.2, TSLP, AC008572.1, WDR36, AC010468.2, RPS3AP21, CAMK4, AC010468.1, AC010275.1, STARD4, STARD4-AS1, HMGN1P13, AC008967.1.
- chr5:112,452,703–113,595,285, 17 genes, copy number 26: HMGB3P16, AC137549.1, LINC02200, APC, CBX3P3, RNU6-482P, AC008575.1, SRP19, REEP5, XBP1P1, ZRSR2P1, DCP2, MCC, AC079465.1, TSSK1B, RNU4ATAC13P, YTHDC2.
- chr5:139,740,951–140,564,781, 25 genes, copy number 12–25 (within-gene range 2–25): PSD2-AS1, AC008667.3, AC008667.4, PSD2, NRG2, AC008667.2, Y_RNA, MALINC1, PURA, IGIP, AC011379.2, CYSTM1, AC011379.1, PFDN1, HBEGF, AC008438.2, SLC4A9, AC008438.1, RNU4-14P, ANKHD1, ANKHD1-EIF4EBP3, AC011399.1, SRA1, EIF4EBP3, APBB3.
- chr5:151,949,571–153,223,543, 5 genes, copy number 12–30 (within-gene range 2–30): LINC01933, AC008571.2, NMUR2, AC008571.1, LINC01470.
- chr5:157,931,258–159,099,916, 18 genes, copy number 11: AC008677.2, RNU2-48P, MARK2P11, AC008677.1, AC008677.3, AC025437.5, AC025437.4, AC025437.6, AC025437.3, AC025437.2, AC025437.1, LINC02227, AC091979.1, AC091979.2, AC091939.1, EBF1, AC136424.2, AC136424.1.
- chr5:159,263,290–160,119,450, 13 genes, copy number 25: UBLCP1, AC008691.1, IL12B, RNU4ATAC2P, LINC01845, AC008703.1, LINC01847, ADRA1B, GAPDHP40, Y_RNA, TTC1, AC068657.1, PWWP2A.
- chr5:161,847,063–163,460,102, 10 genes, copy number 11 (within-gene range 2–11): GABRA1, LINC01202, GABRG2, AC113414.1, RNU6-164P, ARL2BPP5, MRPL57P6, AC008723.1, CCNG1, NUDCD2.
- chr5:165,782,805–168,264,157, 14 genes, copy number 16–22 (within-gene range 2–22): AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1, LINC01947, AC091819.2, AC091819.1, TENM2, AC091820.2, AC091820.1, AC008601.1, AC008708.2, AC008708.1.
- chr5:168,661,733–170,788,650, 28 genes, copy number 11–14 (within-gene range 2–14): SLIT3, SLIT3-AS2, MIR218-2, Y_RNA, AC011389.1, AC011389.2, SLIT3-AS1, MIR585, RNU6-477P, SPDL1, DOCK2, AC008680.1, INSYN2B, MIR378E, FOXI1, KRT18P41, LINC01187, C5orf58, LCP2, AC034199.2, LINC01366, AC034199.1, KCNIP1, KCNMB1, KCNIP1-OT1, AC008619.1, KCNIP1-AS1, AC008514.1.
- chr5:172,834,251–173,809,039, 31 genes, copy number 15 (within-gene range 6–15): ERGIC1, AC008429.1, AC008429.3, RPL26L1, AC008429.2, ATP6V0E1, AC008429.4, SNORA74B, Y_RNA, CREBRF, CDC42P5, AC008378.1, BNIP1, RPL7AP33, NKX2-5, Y_RNA, RNA5SP200, STC2, MIR8056, RNU6-500P, AC016573.1, AC008632.1, AC008663.1, AC008663.3, AC008663.2, BOD1, LINC01863, LINC01942, LINC01484, AC008674.1, LINC01485.
- chr5:175,903,874–177,619,754, 73 genes, copy number 13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 387. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
